Somatic mutation profile of tumor specimen TCGA-H2-A421-01A (aliquot TCGA-H2-A421-01A-11D-A23M-08) from TCGA case TCGA-H2-A421, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 34.7 years (12,657 days).
Specimen TCGA-H2-A421-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 290d511f-dd75-4c0b-a2d0-6c061080a1b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-H2-A421-10A (Blood Derived Normal), aliquot TCGA-H2-A421-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09c63ca5-6c0b-4ac3-a171-33fa15de9e8a

The open-access MAF lists 22 somatic variants for this specimen: 12 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 8, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- C1R | c.1632G>T p.M544I (on ENST00000536053 / NM_001354346.2; = p.M530I on NM_001733.7) | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV73383006; called by muse, mutect2
- EIF3A | c.3635A>T p.D1212V | Missense Mutation (SNP) | VAF 9/194 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.151); catalogued as COSV64961801; called by muse, mutect2
- EXOC7 | c.1366A>G p.S456G (on ENST00000335146 / NM_001145297.4; = p.S374G on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as COSV58742488; called by muse, mutect2
- F10 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.147); catalogued as rs201675411, COSV65021200; called by muse, mutect2, varscan2
- MYBL2 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV53830892; called by muse, mutect2, varscan2
- MYO15A | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV52758650; called by muse, mutect2, varscan2
- NSMAF | c.1571T>G p.V524G | Missense Mutation (SNP) | VAF 26/245 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as COSV50689939; called by muse, mutect2, varscan2
- PCDH15 | c.4301C>T p.A1434V | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.085); catalogued as rs572629527, COSV57265897; called by muse, mutect2, varscan2
- PLA2R1 | c.4159G>A p.E1387K | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs750917637, COSV51780748; called by muse, mutect2
- PLTP | c.175G>T p.G59C | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62465109; called by muse, mutect2
- RLN1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.182); catalogued as COSV99802719; called by muse, mutect2
- ABCC9 | c.3813C>T p.D1271= | Silent (SNP) | VAF 16/216 reads (7%) | catalogued as COSV53975341; called by muse, mutect2
- CLEC16A | c.2379C>T p.F793= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as rs758257284, COSV55490221; called by muse, mutect2
- DNAH9 | c.13260G>A p.L4420= | Silent (SNP) | VAF 13/189 reads (7%) | catalogued as COSV52355589, COSV52369850; called by muse, mutect2
- GPR152 | c.705C>T p.F235= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as rs78290792, COSV56886475; called by muse, mutect2, varscan2
- HPS3 | c.2920C>T p.L974= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV52831297; called by muse, mutect2, varscan2
- LRIG1 | c.1935G>A p.E645= | Silent (SNP) | VAF 12/198 reads (6%) | catalogued as COSV56241841; called by muse, mutect2
- MAGEC1 | c.3252A>G p.V1084= | Silent (SNP) | VAF 108/360 reads (30%) | catalogued as COSV53575023; called by muse, mutect2, varscan2
- THBS4 | c.699C>T p.L233= | Silent (SNP) | VAF 8/87 reads (9%) | catalogued as COSV63469689; called by muse, mutect2
- CDK12 | c.-2G>A | 5'UTR (SNP) | VAF 40/125 reads (32%) | catalogued as COSV101420441; called by mutect2, varscan2
- HTR4 | c.1077-988C>A | Intron (SNP) | VAF 11/52 reads (21%) | catalogued as rs767880023, COSV58797569; called by muse, mutect2, varscan2
